Somatic mutation profile of tumor specimen TCGA-H2-A3RH-01A (aliquot TCGA-H2-A3RH-01A-11D-A21Z-08) from TCGA case TCGA-H2-A3RH, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.3 years (15,068 days).
Specimen TCGA-H2-A3RH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b76447c-f4ec-432c-8cc2-ec2af9caa354.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H2-A3RH-10A (Blood Derived Normal), aliquot TCGA-H2-A3RH-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66a209ea-8aa1-4f35-bf41-84b359815993

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, varscan2
- DLG5 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64946873, COSV64947137; called by muse, mutect2, varscan2
- PHF3 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV50314374; called by muse, mutect2, varscan2
- TUBG1 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV99258739; called by muse, mutect2
- EEF1A1 | c.948_951del p.V317Rfs*27 | Frame Shift Del (DEL) | VAF 39/170 reads (23%) | called by pindel, varscan2
- FAM71F1 | c.624T>A p.P208= | Silent (SNP) | VAF 77/171 reads (45%) | catalogued as COSV59373047; called by muse, mutect2, varscan2
- KRAS | c.180T>A p.G60= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs397517037, COSV55499291, COSV55523567, COSV99782811; ClinVar: uncertain significance; called by muse, varscan2
- TUBG1 | c.321A>G p.G107= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV99258742; called by muse, mutect2
